REBC case REBC-ADJQ — Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine (REBC-THYR)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/664aa6ea-aca7-49a6-ba83-56affd70840b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample REBC-ADJQ-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: EDTA.
- Sample REBC-ADJQ-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
  Slide REBC-ADJQ-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 98; Percent necrosis: 0; Percent stromal cells: 2; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample REBC-ADJQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
  Slide REBC-ADJQ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample SC108191: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample SC108192: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
